Surgical pathology report (de-identified scan), TCGA case TCGA-22-5471, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5471-01A (Primary Tumor).

TCGA-22-5471

DIAGNOSIS:

Lung, left lower lobe and bronchial margins, resection: Invasive grade 3 (of 4) squamous cell carcinoma forming a 3.5 x 2.4 x 2.0 cm mass obliterating the proximal bronchus. There is no pleural involvement. The bronchial margins (submitted separately) are negative for neoplasm..

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (14) left lower paratracheal (station 4L) lymph nodes.
- No tumor is identified in multiple (3) subaortic (station 5) lymph nodes.
- No tumor is identified in multiple (5) subcarinal (station 7) lymph nodes.
- No tumor is identified in a single pulmonary ligament (station 9) lymph node.

Lymph nodes, pulmonary artery, excision:

- No tumor is identified in multiple (3) pulmonary artery lymph nodes.
- No tumor is identified in multiple (7) intrapulmonary peribronchial lymph nodes.

Source: NCI Genomic Data Commons file 4bceff31-5bbe-45a5-b144-8083b1758f3f (TCGA-22-5471.139E042E-6971-4840-97B1-A54988346967.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).